CCDI case PBBWYH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Testis.
https://portal.gdc.cancer.gov/cases/c799d9dc-0380-42b7-b3b9-472f925a8ddf

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 16.1 years (5,897 days).

Biospecimens (3 samples)
- Sample 0DJVOW: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DJVP7: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJVPL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
